Somatic mutation profile of tumor specimen CPT000818 (aliquot CPT000818-0012) from CPTAC case 100004012, project CPTAC-2 (Breast). Sex at birth: female; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 52.7 years (19,253 days).
Specimen CPT000818: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bc8350ec-0d27-4812-a69a-eb73048c14ef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CPT000824 (Blood Derived Normal), aliquot CPT000824-0002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bba65269-757e-47f9-af2c-66e3c97c1f16

The open-access MAF lists 183 somatic variants for this specimen: 126 protein-altering or splice-affecting, 34 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 107, Silent 34, Intron 12, Nonsense Mutation 9, 3'UTR 5, Frame Shift Del 5, RNA 3, In Frame Del 2, 5'Flank 2, Splice Site 2, 5'UTR 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 38/428 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs17849781, CM011015, CM052927, CM120850, CX0910928, COSV52668132, COSV52679740, COSV52684662, COSV52950563; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 83/534 reads (16%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAM9 | c.1588T>C p.S530P | Missense Mutation (SNP) | VAF 33/169 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs751287441; called by muse, mutect2, varscan2
- ADAMTS20 | c.11C>G p.A4G | Missense Mutation (SNP) | VAF 23/179 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV67126281; called by muse, mutect2, varscan2
- AICDA | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 39/348 reads (11%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.821); catalogued as COSV57564653; called by muse, mutect2, varscan2
- ARNT | c.142G>C p.D48H | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV62232302; called by muse, mutect2, varscan2
- ATP11C | c.1450G>C p.D484H | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100557335; called by muse, mutect2, varscan2
- CACNA1B | c.3373G>A p.V1125I | Missense Mutation (SNP) | VAF 50/276 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.125); catalogued as rs570718684; called by muse, mutect2, varscan2
- CACNA1B | c.4756C>T p.R1586C | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs773522880, COSV99500063; called by muse, mutect2
- CCN4 | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 58/606 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as rs753495859, COSV51531014, COSV99137013; called by muse, mutect2
- CLTCL1 | c.1618G>A p.E540K | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.228); catalogued as rs927569939; called by muse, mutect2, varscan2
- DGKZ | c.3121G>C p.D1041H (on ENST00000454345 / NM_001105540.2; = p.D853H on NM_003646.4) | Missense Mutation (SNP) | VAF 24/300 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58993050; called by muse, mutect2
- DHX36 | c.1729T>C p.F577L | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV57677241; called by muse, mutect2, varscan2
- DNASE1L2 | c.72C>G p.I24M | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as rs775189893; called by muse, mutect2, varscan2
- EDEM1 | c.1265A>G p.N422S | Missense Mutation (SNP) | VAF 55/151 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.823); catalogued as rs1463304000; called by muse, mutect2, varscan2
- ELK3 | c.419C>G p.S140* | Nonsense Mutation (SNP) | VAF 25/255 reads (10%) | catalogued as COSV57386043; called by muse, mutect2, varscan2
- EPHA10 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 34/298 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.231); catalogued as COSV100139787; called by muse, mutect2, varscan2
- FLT1 | c.1429G>A p.E477K | Missense Mutation (SNP) | VAF 45/242 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201407326, COSV56720944; called by muse, varscan2
- G6PD | c.821A>G p.E274G | Missense Mutation (SNP) | VAF 18/268 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as CM1111164; called by muse, mutect2
- GPR173 | c.1069T>A p.C357S | Missense Mutation (SNP) | VAF 60/290 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.395); catalogued as COSV100212285, COSV60238062; called by muse, mutect2, varscan2
- GPR4 | c.40C>T p.R14C | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.28); catalogued as rs1244375627, COSV59916145; called by muse, mutect2
- LHB | c.407C>G p.S136* | Nonsense Mutation (SNP) | VAF 89/368 reads (24%) | catalogued as COSV55488032; called by muse, mutect2, varscan2
- LIPT1 | c.964G>T p.E322* | Nonsense Mutation (SNP) | VAF 6/82 reads (7%) | catalogued as COSV60739575; called by muse, mutect2
- MAN2A2 | c.1768C>T p.R590C | Missense Mutation (SNP) | VAF 62/223 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs748000992; called by muse, mutect2, varscan2
- MED13L | c.3700A>T p.T1234S | Missense Mutation (SNP) | VAF 78/463 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs140989788, COSV56132826; called by muse, mutect2, varscan2
- MSH4 | c.937G>C p.D313H | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54209950; called by muse, mutect2, varscan2
- MUC16 | c.13643C>T p.A4548V | Missense Mutation (SNP) | VAF 118/445 reads (27%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.01); catalogued as rs890025502; called by muse, mutect2, varscan2
- NID1 | c.1786C>T p.R596* | Nonsense Mutation (SNP) | VAF 46/274 reads (17%) | catalogued as rs757543518, COSV51618215; called by muse, mutect2, varscan2
- NOTCH4 | c.5726C>G p.P1909R | Missense Mutation (SNP) | VAF 39/237 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.067); catalogued as COSV100901148; called by muse, mutect2, varscan2
- NUFIP2 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV56603507; called by muse, mutect2, varscan2
- PLXNB2 | c.4284C>G p.I1428M | Missense Mutation (SNP) | VAF 25/199 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1440787898; called by muse, mutect2, varscan2
- PRTG | c.602G>C p.G201A | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1355011708; called by muse, mutect2, varscan2
- RNASE6 | c.379G>T p.V127F | Missense Mutation (SNP) | VAF 15/229 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs938131463; called by muse, mutect2
- SGSM2 | c.1825G>C p.E609Q (on ENST00000426855 / NM_001098509.2; = p.E654Q on NM_014853.3) | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.963); catalogued as rs371582761, COSV52156744; called by muse, mutect2
- SHROOM4 | c.1756G>C p.E586Q | Missense Mutation (SNP) | VAF 41/529 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV99174148; called by muse, mutect2
- SLC25A33 | c.94C>G p.L32V | Missense Mutation (SNP) | VAF 25/169 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57021413; called by muse, mutect2, varscan2
- SPRED2 | c.896G>A p.R299Q | Missense Mutation (SNP) | VAF 105/495 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.83); catalogued as rs775586347; called by muse, mutect2, varscan2
- TARS2 | c.1636G>T p.D546Y | Missense Mutation (SNP) | VAF 19/338 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs996789463; called by muse, mutect2
- TTC21A | c.1342G>C p.E448Q | Missense Mutation (SNP) | VAF 93/476 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.093); catalogued as COSV57188889; called by muse, mutect2, varscan2
- UGT2B15 | c.1486G>A p.A496T | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs142432791, COSV100592161; called by muse, mutect2
- VCAN | c.3926C>T p.T1309M | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs149651541; called by muse, mutect2
- XPNPEP2 | c.1430A>C p.E477A | Missense Mutation (SNP) | VAF 29/270 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV64369098; called by muse, mutect2, varscan2
- ZFHX4 | c.2027A>G p.Y676C | Missense Mutation (SNP) | VAF 18/314 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1190611753; called by muse, mutect2
- ZNF280B | c.270T>A p.S90R | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as COSV64529791; called by muse, mutect2, varscan2
- ZP2 | c.455C>G p.S152C | Missense Mutation (SNP) | VAF 17/200 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.625); catalogued as rs758360500; called by muse, mutect2
- ABCB7 | c.2209C>A p.Q737K (on ENST00000373394 / NM_001271696.3; = p.Q738K on NM_004299.6) | Missense Mutation (SNP) | VAF 34/184 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- APC | c.747G>C p.K249N | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- APLP2 | c.2209C>G p.P737A | Missense Mutation (SNP) | VAF 52/217 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- ARHGAP30 | c.1698C>A p.F566L | Missense Mutation (SNP) | VAF 31/191 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ARMH3 | c.1797C>G p.H599Q | Missense Mutation (SNP) | VAF 32/176 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ASIP | c.102G>C p.R34S | Missense Mutation (SNP) | VAF 13/143 reads (9%) | SIFT tolerated (0.77); PolyPhen benign (0.006); called by muse, mutect2
- BRWD1 | c.2349+1G>T p.X783_splice | Splice Site (SNP) | VAF 3/20 reads (15%) | called by muse, mutect2
- CCDC15 | c.2697del p.C900Vfs*49 | Frame Shift Del (DEL) | VAF 16/89 reads (18%) | called by mutect2, pindel, varscan2
- CDC5L | c.264C>G p.I88M | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.656); called by muse, mutect2
- CHAMP1 | c.1064C>G p.S355C | Missense Mutation (SNP) | VAF 70/233 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CIB2 | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 146/461 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- CLEC2B | c.173C>G p.S58* | Nonsense Mutation (SNP) | VAF 14/132 reads (11%) | called by muse, mutect2
- CNNM3 | c.1218C>G p.F406L | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- CNST | c.1539T>A p.N513K | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2
- CRY1 | c.1235G>A p.C412Y | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); called by muse, mutect2
- CSF3R | c.1931G>A p.G644E | Missense Mutation (SNP) | VAF 30/369 reads (8%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.708); called by muse, mutect2
- CYP4A22 | c.1328A>G p.H443R | Missense Mutation (SNP) | VAF 19/286 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); called by muse, mutect2
- DACT1 | c.2100G>C p.E700D | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- DHX33 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- DSCAML1 | c.6052C>G p.P2018A (on ENST00000321322; = p.P1958A on NM_020693.4) | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2
- DYSF | c.4139T>G p.F1380C | Missense Mutation (SNP) | VAF 48/612 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EMILIN1 | c.2810A>C p.N937T | Missense Mutation (SNP) | VAF 22/302 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ERCC6L | c.1847T>A p.F616Y | Missense Mutation (SNP) | VAF 34/156 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FAM189B | c.778G>C p.E260Q | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); called by mutect2, varscan2
- FAT4 | c.11624_11631del p.S3875Nfs*20 | Frame Shift Del (DEL) | VAF 48/284 reads (17%) | called by mutect2, varscan2
- FILIP1 | c.3488C>G p.S1163* | Nonsense Mutation (SNP) | VAF 70/314 reads (22%) | called by muse, varscan2
- GDPD4 | c.479-2A>G p.X160_splice | Splice Site (SNP) | VAF 11/84 reads (13%) | called by mutect2, varscan2
- GLCE | c.1475del p.N492Ifs*18 | Frame Shift Del (DEL) | VAF 78/295 reads (26%) | called by mutect2, pindel, varscan2
- GPR160 | c.878G>C p.W293S | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- GSTK1 | c.530G>A p.R177K | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- HECTD4 | c.12961G>C p.E4321Q | Missense Mutation (SNP) | VAF 33/249 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- HK3 | c.1545G>C p.E515D | Missense Mutation (SNP) | VAF 73/385 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HUS1 | c.35_46del p.C12_H15del | In Frame Del (DEL) | VAF 16/163 reads (10%) | called by mutect2, pindel, varscan2
- ITGBL1 | c.335G>T p.C112F | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- KANSL1 | c.331C>A p.H111N | Missense Mutation (SNP) | VAF 14/157 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); called by muse, mutect2
- KCNN4 | c.37A>G p.R13G | Missense Mutation (SNP) | VAF 18/171 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- KIAA1109 | c.8303C>G p.S2768C | Missense Mutation (SNP) | VAF 14/228 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.299); called by muse, mutect2
- LYPD3 | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 63/229 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MACF1 | c.6673A>T p.N2225Y | Missense Mutation (SNP) | VAF 8/103 reads (8%) | called by muse, mutect2
- MACIR | c.473T>A p.L158H | Missense Mutation (SNP) | VAF 25/220 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- MAGEC3 | c.1590C>A p.D530E | Missense Mutation (SNP) | VAF 36/340 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- MASP1 | c.629C>A p.S210Y | Missense Mutation (SNP) | VAF 105/373 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MED25 | c.501G>C p.E167D | Missense Mutation (SNP) | VAF 117/403 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYO1D | c.2011G>T p.D671Y | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NET1 | c.1054G>A p.D352N (on ENST00000355029 / NM_001047160.3; = p.D298N on NM_005863.5) | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- NKX2-3 | c.270G>T p.Q90H | Missense Mutation (SNP) | VAF 28/243 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- NPR1 | c.386_430del p.T129_L144delinsM | In Frame Del (DEL) | VAF 33/142 reads (23%) | called by pindel, varscan2
- NPR2 | c.2586C>G p.I862M | Missense Mutation (SNP) | VAF 35/310 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OR5A2 | c.534T>G p.F178L | Missense Mutation (SNP) | VAF 89/520 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OSMR | c.1450C>A p.H484N | Missense Mutation (SNP) | VAF 20/215 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.005); called by muse, mutect2
- PCDHGA1 | c.532_547del p.F178Nfs*18 | Frame Shift Del (DEL) | VAF 28/202 reads (14%) | called by mutect2, pindel
- PHACTR3 | c.1190A>G p.K397R | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.39); called by muse, mutect2, varscan2
- PHC3 | c.2099A>C p.Q700P (on ENST00000494943 / NM_001308116.2; = p.Q712P on NM_024947.4) | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.618); called by muse, mutect2, varscan2
- PIP5K1A | c.651G>C p.Q217H (on ENST00000368888 / NM_001135638.2; = p.Q204H on NM_003557.3) | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- RAD52 | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- RARG | c.1134G>T p.R378S | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- RECK | c.2902T>G p.W968G | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); called by muse, mutect2
- REL | c.739C>G p.P247A | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RNF111 | c.2206C>T p.P736S | Missense Mutation (SNP) | VAF 20/269 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2
- RORC | c.820G>C p.V274L | Missense Mutation (SNP) | VAF 85/373 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- SACS | c.12557T>A p.V4186D | Missense Mutation (SNP) | VAF 60/257 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- SALL1 | c.2149T>C p.C717R | Missense Mutation (SNP) | VAF 64/367 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SEPHS2 | c.997C>T p.Q333* | Nonsense Mutation (SNP) | VAF 8/105 reads (8%) | called by muse, mutect2
- SGK2 | c.777G>T p.E259D | Missense Mutation (SNP) | VAF 45/275 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SIPA1L2 | c.5074G>T p.D1692Y | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.07); called by muse, mutect2
- SLC7A9 | c.1087A>C p.T363P | Missense Mutation (SNP) | VAF 31/207 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.489); called by muse, varscan2
- SYP | c.214G>T p.E72* | Nonsense Mutation (SNP) | VAF 18/527 reads (3%) | called by muse, mutect2
- SYTL4 | c.462G>C p.Q154H | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.025); called by muse, mutect2
- TRIM40 | c.775T>A p.*259Rext*63 (on ENST00000376724; = p.*230Rext*63 on NM_138700.4) | Nonstop Mutation (SNP) | VAF 11/262 reads (4%) | called by muse, mutect2
- TRMT9B | c.869C>G p.S290C | Missense Mutation (SNP) | VAF 19/198 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2
- TTC30A | c.1047G>C p.L349F | Missense Mutation (SNP) | VAF 14/246 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2
- TVP23C | c.718C>A p.R240S | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- USP18 | c.1042C>A p.Q348K | Missense Mutation (SNP) | VAF 24/292 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2
- VCPIP1 | c.381C>G p.C127W | Missense Mutation (SNP) | VAF 33/285 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- XIRP2 | c.9546G>C p.K3182N (on ENST00000628543; = p.K3357N on NM_152381.6) | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- XXYLT1 | c.867C>A p.N289K | Missense Mutation (SNP) | VAF 14/268 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2
- YBX2 | c.1069del p.D357Tfs*43 | Frame Shift Del (DEL) | VAF 21/239 reads (9%) | called by mutect2*, pindel
- ZFHX2 | c.5050G>C p.E1684Q | Missense Mutation (SNP) | VAF 43/453 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.015); called by muse, mutect2
- ZNF214 | c.271G>C p.D91H | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2
- ZNF721 | c.2194A>G p.K732E (on ENST00000338977; = p.K744E on NM_133474.4) | Missense Mutation (SNP) | VAF 41/253 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- ZNF75A | c.849C>A p.S283R | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.185); called by muse, mutect2
- AGO2 | c.669G>A p.A223= | Silent (SNP) | VAF 23/310 reads (7%) | catalogued as rs767782553, COSV55045580; called by muse, mutect2
- CEBPZ | c.1677G>A p.T559= | Silent (SNP) | VAF 10/118 reads (8%) | catalogued as COSV99305478; called by muse, mutect2
- COG2 | c.474A>G p.L158= | Silent (SNP) | VAF 6/40 reads (15%) | called by muse, mutect2, varscan2
- CRIP2 | c.462G>A p.E154= | Silent (SNP) | VAF 53/264 reads (20%) | catalogued as COSV100231739; called by muse, mutect2, varscan2
- DMD | c.1041T>A p.A347= | Silent (SNP) | VAF 41/213 reads (19%) | called by muse, mutect2, varscan2
- DNAH17 | c.8280C>T p.V2760= | Silent (SNP) | VAF 44/136 reads (32%) | catalogued as rs777425409; called by muse, mutect2, varscan2
- DOP1B | c.2479C>T p.L827= | Silent (SNP) | VAF 22/216 reads (10%) | called by mutect2, varscan2
- FAM83C | c.2085A>G p.G695= | Silent (SNP) | VAF 28/434 reads (6%) | called by muse, mutect2
- GEM | c.495C>T p.F165= | Silent (SNP) | VAF 47/376 reads (13%) | catalogued as rs571339649, COSV52597064; called by muse, mutect2, varscan2
- ICAM1 | c.750C>A p.V250= | Silent (SNP) | VAF 30/522 reads (6%) | called by muse, mutect2
- ICAM4 | c.342C>G p.L114= | Silent (SNP) | VAF 42/189 reads (22%) | called by muse, mutect2, varscan2
- IFT81 | c.1845A>G p.G615= | Silent (SNP) | VAF 4/70 reads (6%) | called by muse, mutect2
- LRRTM1 | c.561C>G p.L187= | Silent (SNP) | VAF 67/364 reads (18%) | called by muse, mutect2, varscan2
- MAGEB6B | c.849G>A p.P283= | Silent (SNP) | VAF 75/337 reads (22%) | catalogued as rs763257224; called by muse, mutect2, varscan2
- MAST1 | c.3213T>C p.A1071= | Silent (SNP) | VAF 73/272 reads (27%) | catalogued as rs1032343386; called by muse, mutect2, varscan2
- MMP27 | c.423C>A p.V141= | Silent (SNP) | VAF 9/164 reads (5%) | called by muse, mutect2
- MYO15A | c.2745C>T p.D915= | Silent (SNP) | VAF 29/205 reads (14%) | called by muse, mutect2, varscan2
- NOXA1 | c.192C>G p.A64= | Silent (SNP) | VAF 76/308 reads (25%) | called by muse, varscan2
- NR1I2 | c.156C>T p.H52= | Silent (SNP) | VAF 86/446 reads (19%) | catalogued as rs1231067625; called by muse, mutect2, varscan2
- NR1I3 | c.537G>A p.L179= | Silent (SNP) | VAF 30/156 reads (19%) | catalogued as rs750927922; called by muse, mutect2, varscan2
- PGAP4 | c.693C>G p.R231= | Silent (SNP) | VAF 53/704 reads (8%) | catalogued as COSV66387748; called by muse, mutect2
- PPP2R3A | c.930G>C p.L310= | Silent (SNP) | VAF 18/177 reads (10%) | catalogued as rs981274516; called by muse, mutect2, varscan2
- PROX2 | c.231C>T p.L77= | Silent (SNP) | VAF 16/140 reads (11%) | called by muse, mutect2, varscan2
- REEP6 | c.294C>T p.A98= | Silent (SNP) | VAF 32/362 reads (9%) | catalogued as rs767904860; called by muse, mutect2
- RPS24 | c.654C>T p.N218= | Silent (SNP) | VAF 25/199 reads (13%) | catalogued as rs761800402; called by muse, mutect2, varscan2
- SLC12A7 | c.1362G>T p.G454= | Silent (SNP) | VAF 21/213 reads (10%) | catalogued as rs766531124; called by muse, mutect2
- SLC5A1 | c.414C>A p.G138= | Silent (SNP) | VAF 69/429 reads (16%) | called by muse, mutect2, varscan2
- TENT5B | c.492C>T p.I164= | Silent (SNP) | VAF 50/452 reads (11%) | called by mutect2, varscan2
- TFRC | c.912G>A p.G304= | Silent (SNP) | VAF 27/73 reads (37%) | called by muse, mutect2, varscan2
- TLR10 | c.12C>T p.I4= | Silent (SNP) | VAF 7/29 reads (24%) | called by muse, mutect2, varscan2
- USF3 | c.153G>A p.L51= | Silent (SNP) | VAF 9/78 reads (12%) | called by muse, mutect2, varscan2
- ZNF441 | c.1443A>G p.G481= | Silent (SNP) | VAF 20/282 reads (7%) | catalogued as rs1411032536; called by muse, mutect2
- ZNF558 | c.336C>G p.T112= | Silent (SNP) | VAF 11/170 reads (6%) | called by muse, mutect2
- ZSCAN21 | c.462A>C p.A154= | Silent (SNP) | VAF 10/92 reads (11%) | called by muse, mutect2, varscan2
- AC114741.1 | n.186T>G | RNA (SNP) | VAF 10/134 reads (7%) | called by muse, mutect2
- AP003062.1 | n.1050C>G | RNA (SNP) | VAF 31/290 reads (11%) | called by muse, mutect2
- ARHGEF4 | chr2:130915785 C>T | 5'Flank (SNP) | VAF 29/88 reads (33%) | catalogued as rs1442742879, COSV100388599; called by muse, mutect2, varscan2
- ARMCX4 | c.1039-3465_1039-3454del | Intron (DEL) | VAF 22/250 reads (9%) | called by mutect2, pindel
- CENPQ | c.*2G>C | 3'UTR (SNP) | VAF 7/36 reads (19%) | called by muse, mutect2, varscan2
- CFB | c.1409-13C>G | Intron (SNP) | VAF 28/314 reads (9%) | called by muse, mutect2
- DHRS4L2 | chr14:23987249 G>C | 5'Flank (SNP) | VAF 7/42 reads (17%) | called by muse, mutect2, varscan2
- DLD | c.338-29G>C | Intron (SNP) | VAF 57/325 reads (18%) | called by muse, mutect2, varscan2
- ECT2 | c.2656-1397G>C | Intron (SNP) | VAF 6/106 reads (6%) | called by muse, mutect2
- GLRA1 | c.-5G>A | 5'UTR (SNP) | VAF 22/240 reads (9%) | catalogued as COSV99199736; called by muse, mutect2
- HMBS | c.161-22G>C | Intron (SNP) | VAF 36/444 reads (8%) | called by muse, mutect2
- ISY1-RAB43 | c.*300G>A | 3'UTR (SNP) | VAF 20/206 reads (10%) | catalogued as rs780173718; called by muse, mutect2
- LYSMD3 | c.256-935A>C | Intron (SNP) | VAF 21/226 reads (9%) | called by muse, mutect2, varscan2
- MGAT4FP | n.1063_1095del | RNA (DEL) | VAF 32/278 reads (12%) | called by mutect2, pindel
- MMAB | c.*177C>G | 3'UTR (SNP) | VAF 19/240 reads (8%) | called by muse, mutect2
- NT5C3A | c.139-2792G>A | Intron (SNP) | VAF 9/76 reads (12%) | called by muse, mutect2, varscan2
- NTPCR | c.505-1786C>T | Intron (SNP) | VAF 27/129 reads (21%) | catalogued as rs1304667623; called by muse, mutect2, varscan2
- PRPF8 | c.2873-34T>C | Intron (SNP) | VAF 35/447 reads (8%) | called by muse, mutect2
- RNF39 | c.*269C>G | 3'UTR (SNP) | VAF 47/241 reads (20%) | called by muse, mutect2, varscan2
- SPTLC3 | c.1546-357C>T | Intron (SNP) | VAF 9/96 reads (9%) | called by muse, mutect2, varscan2
- SYT13 | c.183+134G>C | Intron (SNP) | VAF 20/264 reads (8%) | called by muse, mutect2
- ZNF747 | c.*302C>A | 3'UTR (SNP) | VAF 28/350 reads (8%) | called by muse, mutect2
- ZNF783 | c.802+3406G>C | Intron (SNP) | VAF 10/86 reads (12%) | called by muse, mutect2, varscan2
